Somatic mutation profile of tumor specimen TCGA-DU-7304-01A (aliquot TCGA-DU-7304-01A-12D-2086-08) from TCGA case TCGA-DU-7304, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 43.6 years (15,931 days).
Specimen TCGA-DU-7304-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1023820-a1c6-4614-ad83-5b9eee79856f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7304-10A (Blood Derived Normal), aliquot TCGA-DU-7304-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e5a3151-b8cb-4803-b4b4-5bdbcb732378

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Splice Site 2, In Frame Del 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 40/113 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP3K1 | c.3989C>T p.S1330L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1287268127, COSV68121509, COSV68122713; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 24/42 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375+1del p.X125_splice | Splice Site (DEL) | VAF 37/102 reads (36%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by mutect2, pindel, varscan2
- AKR7L | c.784A>C p.M262L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761743656, COSV70167506; called by muse, mutect2, varscan2
- ATG5 | c.463A>G p.M155V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.326); catalogued as COSV58347780; called by muse, mutect2, varscan2
- DIPK2A | c.1189G>C p.A397P | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.61); catalogued as COSV59857245; called by muse, mutect2, varscan2
- FAM124A | c.202G>A p.V68I (on ENST00000322475 / NM_001242312.2; = p.V104I on NM_145019.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.654); catalogued as rs1433534038, COSV54475053; called by muse, mutect2, varscan2
- FCGBP | c.6824C>T p.P2275L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1452040648; called by muse, mutect2, varscan2
- HAS3 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 98/243 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1413838677, COSV54706978; called by muse, mutect2, varscan2
- NELL1 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.558); catalogued as rs908099186, COSV54262173; called by muse, mutect2, varscan2
- PLEKHG3 | c.1002G>C p.K334N (on ENST00000394691; = p.K390N on NM_001308147.2) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV55979897; called by muse, mutect2
- PNPLA6 | c.1249C>T p.R417C (on ENST00000414982 / NM_001166111.2; = p.R369C on NM_006702.5) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs998008899, COSV55377935; called by muse, mutect2, varscan2
- SP140 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as rs371799738; called by muse, mutect2
- TPPP2 | c.17A>C p.E6A | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV53875041; called by muse, mutect2, varscan2
- TTN | c.18977A>G p.Q6326R (on ENST00000591111; = p.Q5399R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/292 reads (5%) | PolyPhen benign (0); catalogued as rs1399714010, COSV60043285; called by muse, mutect2
- UBR4 | c.1939-1G>A p.X647_splice | Splice Site (SNP) | VAF 7/70 reads (10%) | catalogued as COSV64389204; called by muse, mutect2, varscan2
- ATRX | c.4919del p.K1640Sfs*6 | Frame Shift Del (DEL) | VAF 40/64 reads (63%) | called by mutect2, pindel, varscan2
- NLGN4X | c.264T>G p.F88L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NR4A1 | c.1391_1393del p.F464del | In Frame Del (DEL) | VAF 32/96 reads (33%) | called by pindel, varscan2
- TMEM236 | c.811A>C p.I271L | Missense Mutation (SNP) | VAF 24/470 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2
- ADAM30 | c.1410C>T p.C470= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs752265647, COSV65561048; called by muse, mutect2, varscan2
- DAPL1 | c.114A>G p.R38= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV59354326; called by muse, mutect2, varscan2
- IL10 | c.190T>C p.L64= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100894728; called by mutect2, varscan2
- LRRC31 | c.837G>A p.R279= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV52980837; called by muse, mutect2
- MECP2 | c.261C>T p.I87= | Silent (SNP) | VAF 54/67 reads (81%) | catalogued as COSV57653684; called by muse, mutect2, varscan2
- SLCO1A2 | c.1989T>C p.D663= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV56601659; called by muse, mutect2, varscan2
- PRND | chr20:4732625 G>A | 3'Flank (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
